Somatic mutation profile of tumor specimen C3N-02728-03 (aliquot CPT0178980006) from CPTAC case C3N-02728, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 54.7 years (19,982 days).
Specimen C3N-02728-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0bd4244-ec7a-4dca-892f-03d1c50c2c8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02728-71 (Blood Derived Normal), aliquot CPT0179080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b5e29e1-1005-48ba-9770-07d4c73c0272

The open-access MAF lists 497 somatic variants for this specimen: 332 protein-altering or splice-affecting, 108 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 293, Silent 108, Intron 29, Nonsense Mutation 19, RNA 11, 5'UTR 7, Splice Site 6, 3'UTR 6, Frame Shift Del 6, Splice Region 5, 5'Flank 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.58del p.S20Qfs*24 | Frame Shift Del (DEL) | VAF 135/360 reads (38%) | catalogued as rs1131691018; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.3890A>T p.Y1297F | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.707); catalogued as rs567861570; called by muse, mutect2
- ADAMTS5 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV53179855; called by muse, mutect2, varscan2
- ADCY10 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 301/534 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100897013; called by muse, mutect2, varscan2
- AGBL1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs779355087; called by muse, mutect2, varscan2
- AHNAK | c.13356G>A p.M4452I | Missense Mutation (SNP) | VAF 57/452 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs778580159; called by muse, mutect2, varscan2
- AKR7L | c.954G>C p.W318C | Missense Mutation (SNP) | VAF 63/562 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70167680; called by muse, mutect2, varscan2
- AL645922.1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 47/522 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1240407549; called by muse, mutect2
- ANKIB1 | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as rs757583305; called by muse, mutect2, varscan2
- BAK1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770151646; called by muse, mutect2, varscan2
- BRIP1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 63/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747568830, COSV52002146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1orf21 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as COSV52404355; called by muse, mutect2, varscan2
- CCNA2 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV52654939; called by muse, mutect2, varscan2
- CDH10 | c.2150G>T p.R717M | Missense Mutation (SNP) | VAF 191/369 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52584402; called by muse, mutect2, varscan2
- CES5A | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51864975; called by muse, mutect2, varscan2
- CHD7 | c.6355G>A p.D2119N | Missense Mutation (SNP) | VAF 219/748 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71110497; called by muse, mutect2, varscan2
- COL22A1 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321970; called by muse, mutect2
- CPA6 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV52721363; called by muse, mutect2
- CPEB4 | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.978); catalogued as rs1184079379; called by muse, mutect2, varscan2
- CYP7B1 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as rs745673560; called by muse, mutect2, varscan2
- DBX2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100224422; called by muse, mutect2, varscan2
- DEPDC5 | c.1607C>G p.P536R | Missense Mutation (SNP) | VAF 144/472 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99834055; called by muse, mutect2, varscan2
- DKK1 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs370680630; called by muse, mutect2, varscan2
- DPEP1 | c.479del p.G160Afs*5 | Frame Shift Del (DEL) | VAF 80/339 reads (24%) | catalogued as COSV99878330; called by mutect2, pindel, varscan2
- DYNC2H1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100518518; called by muse, mutect2, varscan2
- EIF5B | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs1466611823, COSV56811610; called by muse, varscan2
- EPHA3 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60706341; called by muse, mutect2, varscan2
- ESYT1 | c.2828G>T p.G943V | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57272138; called by muse, mutect2, varscan2
- EYS | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV65499825; called by muse, mutect2, varscan2
- FAU | c.75+3A>G | Splice Region (SNP) | VAF 189/461 reads (41%) | catalogued as rs756092466; called by muse, mutect2, varscan2
- FPGS | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs553086956; called by muse, mutect2, varscan2
- FRAS1 | c.4064C>A p.A1355D | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53621512; called by muse, mutect2, varscan2
- GBP4 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV63254226; called by muse, mutect2
- GLYATL2 | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99780477; called by muse, mutect2, varscan2
- GLYATL2 | c.857G>T p.W286L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54850160; called by muse, mutect2, varscan2
- GNAO1 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV99341352; called by muse, mutect2, varscan2
- H2AC11 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs1383044017, COSV100345610, COSV60361677; called by muse, varscan2
- HAUS1 | c.474A>G p.Q158= | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56363172; called by muse, mutect2, varscan2
- HLA-DQB2 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1374839974; called by muse, varscan2
- HROB | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776313962; called by muse, mutect2
- HSF1 | c.1506A>C p.E502D | Missense Mutation (SNP) | VAF 61/541 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1164423085; called by muse, mutect2, varscan2
- ID1 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.31); catalogued as rs760422390; called by muse, mutect2, varscan2
- IFNL1 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.181); catalogued as COSV100373665; called by muse, mutect2, varscan2
- IGFBP6 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs770998073; called by muse, mutect2, varscan2
- IGKJ4 | c.36A>T p.K12N | Missense Mutation (SNP) | VAF 116/401 reads (29%) | PolyPhen possibly damaging (0.548); catalogued as rs78964890; called by muse, mutect2, varscan2
- IGSF6 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 70/516 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs970342564; called by muse, mutect2, varscan2
- IL7R | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 93/449 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57409966; called by muse, mutect2, varscan2
- INHBA | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99638532; called by muse, mutect2, varscan2
- IQUB | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 38/126 reads (30%) | catalogued as COSV61237549; called by muse, mutect2, varscan2
- JAKMIP1 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 208/581 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV51534944; called by muse, mutect2, varscan2
- KIF6 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV104380340; called by muse, mutect2, varscan2
- LHFPL3 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV101308805; called by muse, mutect2, varscan2
- LRP2 | c.5830G>A p.E1944K | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV55549631; called by muse, mutect2, varscan2
- MACROD2 | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV53985682; called by muse, mutect2, varscan2
- MED13L | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs377144746; called by muse, mutect2
- MINDY4 | c.1678-8C>T | Splice Region (SNP) | VAF 118/311 reads (38%) | catalogued as rs761507724; called by muse, mutect2, varscan2
- MORC1 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs779937263; called by muse, mutect2, varscan2
- MUC16 | c.41132C>A p.P13711H | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.995); catalogued as rs1419763523, COSV66690113; called by muse, mutect2, varscan2
- MYH2 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55434247; called by muse, mutect2, varscan2
- MYRFL | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205408126, COSV100185184; called by muse, mutect2, varscan2
- OR10G2 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 53/478 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1173776758, COSV73390358; called by muse, mutect2, varscan2
- OR10J3 | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 63/569 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs374370080; called by muse, mutect2, varscan2
- OR2T1 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV63542506; called by muse, mutect2, varscan2
- OR52E8 | c.388A>T p.I130F | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1384539848; called by muse, mutect2
- OSBPL8 | c.116C>A p.T39K | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); catalogued as COSV53887398; called by muse, mutect2, varscan2
- PCNX3 | c.5894C>T p.A1965V | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs748696303; called by muse, mutect2, varscan2
- PHACTR3 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 129/293 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV63028452; called by muse, mutect2, varscan2
- PLCB2 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs759357184; called by muse, mutect2, varscan2
- PLCH2 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370809933; called by muse, mutect2, varscan2
- POU6F1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 26/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61327389; called by muse, mutect2
- PPP4R2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1224564140; called by muse, varscan2
- PPT1 | c.622C>T p.R208W (on ENST00000433473; = p.R209W on NM_000310.4) | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs766392111; called by muse, mutect2
- PRKCE | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60324784; called by muse, mutect2, varscan2
- PTPN13 | c.3953G>T p.R1318L (on ENST00000411767 / NM_080683.3; = p.R1299L on NM_006264.3) | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs749733308; called by muse, mutect2
- QARS1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764216449, COSV60275524; ClinVar: uncertain significance; called by muse, mutect2
- RASSF1 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 167/388 reads (43%) | catalogued as rs765311131; called by muse, mutect2, varscan2
- RASSF3 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs371975809; called by muse, mutect2, varscan2
- RBM4B | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 214/574 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV100026481; called by muse, mutect2, varscan2
- RBM7 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100972168; called by muse, mutect2, varscan2
- REG3A | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138199548; called by muse, mutect2, varscan2
- RET | c.2196A>C p.E732D | Missense Mutation (SNP) | VAF 56/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100393740; called by muse, mutect2, varscan2
- RIN3 | c.1843T>C p.Y615H | Missense Mutation (SNP) | VAF 22/431 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99379105; called by muse, mutect2
- RIPK2 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1447172803; called by muse, mutect2
- RNF182 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs370563371; called by muse, mutect2, varscan2
- ROBO2 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100165204, COSV59922723; called by muse, varscan2
- ROS1 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 205/466 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs759714879, COSV63851066; called by muse, mutect2, varscan2
- RSAD1 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV99364234; called by muse, mutect2, varscan2
- SERPINH1 | c.459C>G p.H153Q | Missense Mutation (SNP) | VAF 93/541 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1467115947; called by muse, mutect2, varscan2
- SGPP1 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as rs756586151; called by muse, mutect2
- SGSH | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs979896080; called by muse, mutect2, varscan2
- SH3TC1 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1040416168, COSV55286810; called by muse, mutect2, varscan2
- SHANK1 | c.2914G>T p.G972W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.844); catalogued as rs1374552020; called by muse, mutect2
- SHCBP1L | c.771G>T p.R257S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs766701997; called by muse, mutect2, varscan2
- SLC24A4 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100105452, COSV54107412; called by muse, mutect2, varscan2
- SLC6A11 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as rs1368996516; called by muse, mutect2
- SMCHD1 | c.5797C>G p.L1933V | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV57967321; called by muse, mutect2, varscan2
- SNIP1 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.03); catalogued as rs766348411; called by muse, mutect2, varscan2
- SOAT2 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV56861947; called by muse, mutect2, varscan2
- SSTR4 | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV99658809; called by muse, mutect2, varscan2
- SUFU | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 50/477 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs142672533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULF1 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52692266; called by muse, mutect2, varscan2
- TBC1D1 | c.3263G>C p.S1088T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs1222128281; called by muse, mutect2, varscan2
- TBC1D23 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1334826104; called by muse, varscan2
- TBX22 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100960655; called by muse, mutect2, varscan2
- TINAG | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV52515248; called by muse, mutect2
- TRA2B | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52024922; called by muse, mutect2, varscan2
- TRAT1 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV99849393; called by muse, mutect2, varscan2
- TTC29 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV57275027; called by muse, mutect2, varscan2
- UBXN10 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66772672; called by muse, mutect2, varscan2
- USP31 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs766847677, COSV54851860; called by muse, mutect2, varscan2
- USP42 | c.3415C>G p.L1139V | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs766792219; called by muse, mutect2
- VN1R2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs370380201; called by muse, mutect2, varscan2
- ZFHX4 | c.8735C>T p.P2912L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50642449; called by muse, mutect2, varscan2
- ZFP42 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs761076682; called by muse, mutect2
- ZFPM2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 128/552 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.696); catalogued as COSV65874460; called by muse, mutect2, varscan2
- ZNF551 | c.669C>A p.Y223* | Nonsense Mutation (SNP) | VAF 55/330 reads (17%) | catalogued as rs756468700; called by muse, mutect2, varscan2
- ZNF610 | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as COSV58345482; called by muse, mutect2, varscan2
- ABCA12 | c.3789T>G p.I1263M (on ENST00000272895 / NM_173076.3; = p.I945M on NM_015657.3) | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ABCA6 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABRAXAS2 | c.72+1G>T p.X24_splice | Splice Site (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- ADAM22 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ADAMTS13 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 134/712 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- ADAMTS20 | c.5278G>T p.G1760C | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- ADAMTS7 | c.913A>G p.K305E | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ADARB2 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 243/501 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRV1 | c.2610G>T p.L870F | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCYL1 | c.1318-2A>G p.X440_splice | Splice Site (SNP) | VAF 45/254 reads (18%) | called by muse, mutect2, varscan2
- AHNAK2 | c.5632G>T p.A1878S | Missense Mutation (SNP) | VAF 298/574 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.295); called by muse, varscan2
- AK8 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK1 | c.2890C>A p.P964T | Missense Mutation (SNP) | VAF 100/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANK2 | c.9151G>C p.D3051H | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKK1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANKRD24 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- AOAH | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ATRNL1 | c.4014G>T p.Q1338H | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BAZ2B | c.5985A>C p.K1995N | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.179); called by muse, mutect2
- BCHE | c.1094T>A p.F365Y | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- BCL6 | c.1461G>C p.E487D | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); called by muse, mutect2
- BTAF1 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- C12orf50 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- CACNA1S | c.5493G>T p.E1831D | Missense Mutation (SNP) | VAF 46/902 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.315); called by muse, mutect2
- CBWD2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- CBY2 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CCDC144A | c.3376G>A p.D1126N | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.546); called by muse, mutect2
- CD33 | c.706C>G p.Q236E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CD7 | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 200/648 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CD86 | c.266A>T p.D89V (on ENST00000330540 / NM_175862.5; = p.D83V on NM_006889.4) | Missense Mutation (SNP) | VAF 129/371 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH23 | c.2268C>A p.N756K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- CDH8 | c.2251G>T p.G751C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK5RAP2 | c.5569T>G p.F1857V | Missense Mutation (SNP) | VAF 182/377 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, varscan2
- CENPF | c.1291A>G p.M431V | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP74 | c.3679T>G p.Y1227D | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CIAO2B | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 137/495 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CLSPN | c.2317A>T p.N773Y | Missense Mutation (SNP) | VAF 190/562 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CNGB3 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL24A1 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 90/143 reads (63%) | called by muse, mutect2, varscan2
- COL6A5 | c.6669G>T p.K2223N (on ENST00000312481; = p.K2219N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/469 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COMMD2 | c.20A>G p.E7G | Missense Mutation (SNP) | VAF 16/361 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.085); called by muse, mutect2
- CPED1 | c.2295C>A p.C765* | Nonsense Mutation (SNP) | VAF 124/381 reads (33%) | called by muse, mutect2, varscan2
- CYP4F2 | c.1151G>C p.C384S | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DBF4B | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCHS1 | c.4391A>G p.D1464G | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DDI1 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- DENND4A | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 54/189 reads (29%) | called by muse, mutect2, varscan2
- DES | c.1184A>T p.K395M | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH10 | c.505G>A p.E169K (on ENST00000409039; = p.E108K on NM_207437.3) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- DOCK1 | c.785G>C p.R262P | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- DPP10 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 93/301 reads (31%) | called by muse, mutect2, varscan2
- DST | c.9658A>G p.R3220G | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC1H1 | c.11468T>G p.F3823C | Missense Mutation (SNP) | VAF 61/575 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EEA1 | c.102T>A p.N34K | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2
- EN1 | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ENPP1 | c.1482C>G p.F494L | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ENPP2 | c.529T>A p.S177T | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EYS | c.3089G>A p.C1030Y | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FAM160A2 | c.2467A>G p.K823E (on ENST00000449352 / NM_001098794.2; = p.K837E on NM_032127.4) | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM71E1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FHL5 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- FOS | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXO6 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 104/531 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FREM3 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FSIP2 | c.19258C>A p.Q6420K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- GABPB2 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT5 | c.1531A>T p.T511S | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- GEN1 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GIP | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- GJD3 | c.538T>G p.F180V | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GMNC | c.349T>G p.S117A | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2
- GNAO1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GRIK2 | c.1764G>T p.E588D | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSDMA | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HACD2 | c.634T>A p.F212I | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.2807del p.G936Afs*3 | Frame Shift Del (DEL) | VAF 64/258 reads (25%) | called by mutect2, pindel, varscan2
- HLA-DPB1 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMCN1 | c.2663-1G>T p.X888_splice | Splice Site (SNP) | VAF 71/493 reads (14%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSPA12A | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HSPA9 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- ICAM1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 125/368 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGF2BP3 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- IGHV3-64 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- IGHV3-64 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 217/825 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IKBKB | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- IL33 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ING1 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IQSEC3 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 68/1132 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.072); called by muse, mutect2
- JAKMIP3 | c.1025A>T p.K342M | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KATNAL2 | c.547A>G p.R183G (on ENST00000356157 / NM_001353899.1; = p.R111G on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIAA1109 | c.8683G>A p.G2895R | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL36 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- KRT34 | c.1279T>C p.C427R | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- LAMB4 | c.3940T>C p.Y1314H | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- LINC01036 | n.153C>G | Splice Region (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- LIPA | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LPA | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 15/782 reads (2%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC32 | c.1643T>A p.F548Y | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAG | c.1692C>G p.I564M | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MAPK6 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MED17 | c.774+4T>G | Splice Region (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- MEP1A | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MET | c.2454A>T p.K818N | Missense Mutation (SNP) | VAF 153/489 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MFSD1 | c.330-1G>A p.X110_splice | Splice Site (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- MGAT4C | c.1032T>A p.S344R | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MSC | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 163/607 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCL1 | c.5171A>T p.Q1724L (on ENST00000306329 / NM_001378206.1; = p.Q1405L on NM_015210.4) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MUC12 | c.15598A>G p.T5200A (on ENST00000379442; = p.T5057A on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.22); called by muse, mutect2
- MUC16 | c.22603G>C p.E7535Q | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC2 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- MX2 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYADML2 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MYH7B | c.4893C>A p.C1631* | Nonsense Mutation (SNP) | VAF 120/395 reads (30%) | called by muse, mutect2, varscan2
- MYOF | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- NBEA | c.7963C>T p.P2655S | Missense Mutation (SNP) | VAF 147/260 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOA3 | c.965-2A>T p.X322_splice | Splice Site (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- NEDD1 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NHLRC2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NID2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- NLRC3 | c.1042G>T p.G348W | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2
- NLRP2 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 12/351 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); called by muse, mutect2
- NLRP3 | c.2641C>A p.Q881K | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NLRP3 | c.2728C>A p.Q910K | Missense Mutation (SNP) | VAF 66/575 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.2913C>G p.C971W | Missense Mutation (SNP) | VAF 298/760 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPA5 | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 25/661 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- NPY5R | c.342C>A p.C114* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- NTRK1 | c.1538A>G p.K513R | Missense Mutation (SNP) | VAF 527/955 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NTS | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- NUP153 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- NUP93 | c.2334C>G p.I778M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OR4Q3 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- OR4Q3 | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 60/735 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- OR52L1 | c.989G>T p.*330Lext*? | Nonstop Mutation (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- OR5D14 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OR6F1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OTOP1 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PARD3 | c.2968A>G p.R990G | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PCDHB16 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PDCD11 | c.1082G>C p.C361S | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLEKHG4 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- POLR3F | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- POTEJ | c.1537G>T p.V513F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by mutect2, varscan2
- PPARGC1A | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PPP2R5E | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRUNE2 | c.2800C>G p.L934V | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- R3HDML | c.618C>G p.N206K | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RABGEF1 | c.841G>T p.V281L (on ENST00000439720 / NM_001287061.2; = p.V268L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RANBP10 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RB1CC1 | c.4699G>T p.A1567S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM14 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 59/358 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- RICTOR | c.114A>T p.L38F | Missense Mutation (SNP) | VAF 116/284 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNF186 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 231/389 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- RPH3A | c.1340G>T p.R447L (on ENST00000389385 / NM_001143854.2; = p.R443L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RUFY3 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- RUNX1T1 | c.1321G>C p.V441L (on ENST00000265814 / NM_001198628.1; = p.V414L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- RYR2 | c.3441G>T p.Q1147H | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); called by muse, varscan2
- SART3 | c.2056G>A p.G686R (on ENST00000228284; = p.G668R on NM_014706.4) | Missense Mutation (SNP) | VAF 189/500 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SCN10A | c.315T>A p.S105R | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SENP6 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SESN1 | c.286G>T p.E96* (on ENST00000356644 / NM_001199933.1; = p.E155* on NM_014454.3) | Nonsense Mutation (SNP) | VAF 88/298 reads (30%) | called by muse, mutect2, varscan2
- SGIP1 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SIGLEC8 | c.562dup p.M188Nfs*88 | Frame Shift Ins (INS) | VAF 28/166 reads (17%) | called by mutect2, pindel, varscan2
- SKAP2 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2
- SLC24A4 | c.1447G>T p.G483W | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC5A9 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SMYD3 | c.1033G>C p.E345Q (on ENST00000490107 / NM_001375962.1; = p.E286Q on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SNTG2 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORBS2 | c.298A>C p.T100P (on ENST00000284776 / NM_021069.5; = p.T146P on NM_003603.6) | Missense Mutation (SNP) | VAF 21/319 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORCS3 | c.1530C>A p.D510E | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPDYE4 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPEF2 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- SPINT1 | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SPNS2 | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTBN1 | c.5717G>T p.R1906L | Missense Mutation (SNP) | VAF 122/372 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SRPRB | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.066); called by muse, mutect2
- STAMBPL1 | c.1051A>T p.T351S | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- STK11IP | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- SUCO | c.3660A>G p.I1220M | Missense Mutation (SNP) | VAF 116/235 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYNE1 | c.11254-2A>T p.X3752_splice (on ENST00000367255 / NM_182961.4; = p.X3737_splice on NM_033071.3) | Splice Site (SNP) | VAF 64/149 reads (43%) | called by muse, mutect2, varscan2
- TANGO2 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 166/251 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBPL2 | c.1110A>T p.K370N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TEAD3 | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TENM1 | c.2201G>T p.G734V | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX52 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- TGFBRAP1 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.312); called by muse, mutect2
- TLL2 | c.2963del p.R988Pfs*26 | Frame Shift Del (DEL) | VAF 38/236 reads (16%) | called by mutect2, pindel, varscan2
- TMEM108 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 300/560 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM130 | c.427A>C p.T143P | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TMPRSS15 | c.3053T>G p.L1018R | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TNFAIP1 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 139/440 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNN | c.727T>A p.C243S | Missense Mutation (SNP) | VAF 123/238 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- TRIM46 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 98/620 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPC4AP | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRPM1 | c.4664G>C p.G1555A | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSHZ1 | c.1497G>T p.K499N (on ENST00000580243 / NM_001308210.2; = p.K454N on NM_005786.6) | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- TYR | c.352T>A p.L118M | Missense Mutation (SNP) | VAF 105/485 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- UBIAD1 | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 78/1064 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.717); called by muse, mutect2
- UGT2B7 | c.1411A>C p.K471Q | Missense Mutation (SNP) | VAF 142/385 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- UTP4 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 172/1152 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- WBP11 | c.1841A>T p.K614I | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.388); called by muse, mutect2
- WDR49 | c.1581C>A p.F527L (on ENST00000308378 / NM_001366158.1; = p.F868L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- WIPF1 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by mutect2, varscan2
- XBP1 | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- XKR7 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 23/433 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.361); called by muse, mutect2
- YME1L1 | c.1961G>T p.S654I (on ENST00000326799 / NM_139312.3; = p.S597I on NM_014263.4) | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.589); called by muse, mutect2
- ZBTB14 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ZCCHC2 | c.1001del p.P334Qfs*24 | Frame Shift Del (DEL) | VAF 71/298 reads (24%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.3172G>T p.G1058* | Nonsense Mutation (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- ZNF33B | c.915A>T p.E305D | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF37A | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.806del p.C269Lfs*44 | Frame Shift Del (DEL) | VAF 37/178 reads (21%) | called by mutect2, pindel, varscan2
- ZNF737 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2
- ZNF883 | c.464G>C p.C155S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC9 | c.906A>G p.T302= | Silent (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- ADRA1A | c.1272G>T p.V424= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2
- AGMO | c.891C>A p.V297= | Silent (SNP) | VAF 41/183 reads (22%) | called by muse, mutect2, varscan2
- ANKRD11 | c.5532C>T p.A1844= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1364754392; called by muse, mutect2, varscan2
- ARHGAP15 | c.1095G>T p.P365= | Silent (SNP) | VAF 77/234 reads (33%) | catalogued as COSV54501758; called by muse, mutect2, varscan2
- AUH | c.6G>T p.A2= | Silent (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- AXIN1 | c.1377C>T p.L459= | Silent (SNP) | VAF 234/787 reads (30%) | called by muse, mutect2, varscan2
- CASP12 | c.351T>A p.S117= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- CCDC85A | c.1626A>G p.Q542= | Silent (SNP) | VAF 61/287 reads (21%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3801G>A p.E1267= | Silent (SNP) | VAF 223/925 reads (24%) | catalogued as rs752140867, COSV61348754; called by muse, mutect2, varscan2
- CLSTN2 | c.174A>T p.T58= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- CNTLN | c.1413A>G p.L471= | Silent (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- COL6A5 | c.4527C>A p.G1509= | Silent (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- CPSF1 | c.555C>T p.F185= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- CSNK1D | c.741A>G p.E247= | Silent (SNP) | VAF 30/784 reads (4%) | called by muse, mutect2
- CSRNP1 | c.351C>T p.H117= | Silent (SNP) | VAF 112/258 reads (43%) | called by muse, mutect2, varscan2
- CST1 | c.291C>A p.S97= | Silent (SNP) | VAF 134/513 reads (26%) | called by muse, mutect2, varscan2
- DAZL | c.63G>A p.L21= | Silent (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- DCAF7 | c.375C>G p.S125= | Silent (SNP) | VAF 40/185 reads (22%) | called by muse, mutect2, varscan2
- DNAH6 | c.8037T>A p.S2679= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- DNAH7 | c.10362G>T p.G3454= | Silent (SNP) | VAF 29/99 reads (29%) | called by mutect2, varscan2
- DNAH8 | c.11070C>A p.I3690= | Silent (SNP) | VAF 116/374 reads (31%) | called by muse, mutect2, varscan2
- DOCK4 | c.4935A>C p.S1645= | Silent (SNP) | VAF 53/209 reads (25%) | called by muse, mutect2, varscan2
- DPP6 | c.183C>T p.G61= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1377059145; called by muse, varscan2
- DYRK4 | c.1056G>A p.G352= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1565543994, COSV50537826; called by muse, mutect2, varscan2
- EIF2B5 | c.807A>G p.T269= (on ENST00000647909; = p.T261= on NM_003907.3) | Silent (SNP) | VAF 464/677 reads (69%) | called by muse, mutect2, varscan2
- EPHB6 | c.339A>C p.A113= | Silent (SNP) | VAF 43/852 reads (5%) | called by muse, mutect2
- FTCD | c.343C>T p.L115= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as rs772011871; called by muse, mutect2
- FXR2 | c.1932C>T p.D644= | Silent (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2
- GABRG1 | c.72C>A p.V24= | Silent (SNP) | VAF 49/276 reads (18%) | catalogued as COSV54953539; called by muse, mutect2, varscan2
- GLP2R | c.1317C>A p.A439= | Silent (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- GTF3C1 | c.4542A>C p.R1514= | Silent (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
- HECTD4 | c.1692A>C p.L564= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- HEMK1 | c.129A>G p.E43= | Silent (SNP) | VAF 37/234 reads (16%) | called by muse, mutect2, varscan2
- IFTAP | c.93A>G p.T31= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- IGFBP2 | c.543C>T p.L181= | Silent (SNP) | VAF 89/347 reads (26%) | called by muse, mutect2, varscan2
- IL22 | c.165C>A p.R55= | Silent (SNP) | VAF 54/181 reads (30%) | called by muse, mutect2, varscan2
- ITCH | c.2313A>G p.Q771= (on ENST00000262650 / NM_001257137.3; = p.Q730= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/310 reads (40%) | catalogued as rs766352760; called by muse, mutect2, varscan2
- ITGB2 | c.642C>A p.S214= | Silent (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- ITPRIPL1 | c.294C>T p.A98= (on ENST00000439118 / NM_001008949.3; = p.A106= on NM_178495.6) | Silent (SNP) | VAF 85/294 reads (29%) | catalogued as rs765295483, COSV100742270; called by muse, varscan2
- KCTD13 | c.492C>A p.A164= | Silent (SNP) | VAF 9/226 reads (4%) | called by muse, mutect2
- KDM2B | c.1866C>T p.T622= | Silent (SNP) | VAF 149/659 reads (23%) | catalogued as rs1555292050; called by muse, mutect2, varscan2
- KRT31 | c.60C>A p.P20= | Silent (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- KRT79 | c.1410T>C p.T470= | Silent (SNP) | VAF 50/299 reads (17%) | catalogued as COSV100398455; called by muse, mutect2, varscan2
- KRTAP10-1 | c.462C>A p.P154= | Silent (SNP) | VAF 141/960 reads (15%) | called by muse, mutect2, varscan2
- LAMA5 | c.999C>T p.C333= | Silent (SNP) | VAF 111/671 reads (17%) | catalogued as rs752120644; called by muse, mutect2, varscan2
- LEO1 | c.1452C>G p.V484= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs777129529; called by muse, mutect2, varscan2
- LMNTD2 | c.1875G>A p.P625= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs374021224; called by muse, mutect2, varscan2
- LRFN2 | c.2065C>A p.R689= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- MAGEE1 | c.1386G>T p.L462= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- MAP1S | c.1522C>A p.R508= | Silent (SNP) | VAF 63/221 reads (29%) | called by muse, mutect2, varscan2
- MUC19 | c.903C>A p.S301= | Silent (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2
- MYO5A | c.4059G>C p.L1353= | Silent (SNP) | VAF 81/431 reads (19%) | called by muse, mutect2, varscan2
- NDUFS8 | c.381C>T p.T127= | Silent (SNP) | VAF 106/660 reads (16%) | catalogued as rs751027827; called by muse, mutect2, varscan2
- NHEJ1 | c.459A>G p.L153= | Silent (SNP) | VAF 74/371 reads (20%) | catalogued as rs1239338671; called by muse, mutect2, varscan2
- NHS | c.2250G>T p.A750= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as COSV101196877, COSV66271468; called by muse, mutect2, varscan2
- NID2 | c.420G>C p.V140= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- NLRP6 | c.501A>G p.E167= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as rs1217663219, COSV56461032; called by muse, mutect2, varscan2
- OR2B3 | c.345G>A p.L115= | Silent (SNP) | VAF 38/160 reads (24%) | called by muse, mutect2, varscan2
- OR8D4 | c.174C>A p.P58= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV58429866; called by muse, mutect2, varscan2
- OR8K1 | c.297T>G p.S99= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV54403904, COSV99687473; called by muse, mutect2
- OTOG | c.1944C>A p.T648= | Silent (SNP) | VAF 99/227 reads (44%) | called by muse, mutect2, varscan2
- PATE1 | c.324C>A p.V108= | Silent (SNP) | VAF 52/149 reads (35%) | called by muse, mutect2, varscan2
- PBX1 | c.51C>G p.A17= | Silent (SNP) | VAF 37/402 reads (9%) | catalogued as rs1057295149; called by muse, mutect2
- PCBP2 | c.810C>T p.S270= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- PCDHGA12 | c.2601A>G p.G867= | Silent (SNP) | VAF 91/366 reads (25%) | called by mutect2, varscan2
- PDE8A | c.975G>T p.V325= | Silent (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- PHACTR2 | c.576C>A p.P192= | Silent (SNP) | VAF 110/457 reads (24%) | called by mutect2, varscan2
- PIP5KL1 | c.534G>T p.P178= | Silent (SNP) | VAF 54/288 reads (19%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2442G>T p.V814= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2
- POM121L2 | c.2022G>A p.R674= | Silent (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- PRPF38B | c.1312A>C p.R438= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- PSMC6 | c.12C>G p.P4= | Silent (SNP) | VAF 55/207 reads (27%) | called by muse, mutect2, varscan2
- PTPRN | c.933C>T p.G311= | Silent (SNP) | VAF 89/269 reads (33%) | catalogued as COSV55351953; called by muse, mutect2, varscan2
- PTPRZ1 | c.3462C>T p.D1154= | Silent (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- RBM33 | c.3009A>G p.P1003= | Silent (SNP) | VAF 140/487 reads (29%) | called by muse, mutect2, varscan2
- REG3A | c.111G>T p.R37= | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as COSV59410181; called by muse, mutect2, varscan2
- RIN1 | c.1599C>A p.G533= | Silent (SNP) | VAF 20/132 reads (15%) | called by muse, mutect2
- RP1L1 | c.6000A>C p.V2000= | Silent (SNP) | VAF 139/477 reads (29%) | called by muse, mutect2, varscan2
- SAPCD2 | c.798C>T p.R266= | Silent (SNP) | VAF 49/218 reads (22%) | called by muse, mutect2, varscan2
- SH2B2 | c.1785G>T p.A595= | Silent (SNP) | VAF 121/337 reads (36%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.990C>A p.I330= | Silent (SNP) | VAF 33/214 reads (15%) | called by muse, mutect2, varscan2
- SKOR2 | c.648C>G p.T216= | Silent (SNP) | VAF 106/793 reads (13%) | catalogued as rs1481783458; called by muse, mutect2, varscan2
- SLC39A7 | c.720G>A p.V240= | Silent (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- SLC5A4 | c.117G>A p.V39= | Silent (SNP) | VAF 49/79 reads (62%) | called by muse, mutect2, varscan2
- SLC6A3 | c.942G>T p.A314= | Silent (SNP) | VAF 445/971 reads (46%) | catalogued as rs780728481; called by muse, mutect2, varscan2
- SLC7A9 | c.546G>T p.A182= | Silent (SNP) | VAF 111/465 reads (24%) | catalogued as COSV50083711; called by muse, mutect2, varscan2
- SLC9C2 | c.2544T>C p.N848= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as rs770850323; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1899C>A p.I633= (on ENST00000540229 / NM_001371097.1; = p.I572= on NM_001009562.4) | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs776071568, COSV67443285; called by muse, mutect2, varscan2
- SRMS | c.153C>T p.P51= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as rs746157693; called by muse, mutect2
- STS | c.1152G>A p.Q384= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- TAAR2 | c.732T>C p.N244= (on ENST00000367931 / NM_001033080.1; = p.N199= on NM_014626.3) | Silent (SNP) | VAF 115/237 reads (49%) | called by muse, mutect2, varscan2
- TACR1 | c.231G>A p.A77= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as COSV59479285; called by muse, mutect2, varscan2
- TET2 | c.3945C>T p.D1315= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- TEX15 | c.7566C>A p.V2522= (on ENST00000256246; = p.V2905= on NM_001350162.2) | Silent (SNP) | VAF 72/215 reads (33%) | catalogued as COSV56348365; called by muse, mutect2, varscan2
- THBD | c.1297C>T p.L433= | Silent (SNP) | VAF 163/1372 reads (12%) | called by muse, mutect2, varscan2
- TMEM239 | c.15T>A p.T5= | Silent (SNP) | VAF 38/316 reads (12%) | called by muse, mutect2, varscan2
- TMTC1 | c.84G>T p.G28= | Silent (SNP) | VAF 15/254 reads (6%) | called by muse, mutect2
- TOMM20L | c.117C>T p.F39= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- TRAPPC12 | c.1893C>T p.L631= | Silent (SNP) | VAF 11/236 reads (5%) | catalogued as rs769928088, COSV100160901; called by muse, mutect2
- VAC14 | c.573C>T p.A191= | Silent (SNP) | VAF 71/251 reads (28%) | called by muse, mutect2, varscan2
- VN1R2 | c.609A>G p.V203= | Silent (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
- VWF | c.2112G>A p.K704= | Silent (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- ZC3H4 | c.1914G>T p.P638= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs200656728; called by muse, mutect2, varscan2
- ZIM3 | c.657G>A p.E219= | Silent (SNP) | VAF 52/133 reads (39%) | catalogued as COSV54146322; called by muse, mutect2, varscan2
- ZMAT3 | c.141T>A p.L47= | Silent (SNP) | VAF 453/649 reads (70%) | called by muse, mutect2, varscan2
- ZNF564 | c.1623A>G p.S541= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs761093145; called by muse, mutect2, varscan2
- ZYG11A | c.1314C>T p.P438= | Silent (SNP) | VAF 104/160 reads (65%) | called by muse, mutect2, varscan2
- ABCC8 | c.-7C>A | 5'UTR (SNP) | VAF 52/146 reads (36%) | called by muse, mutect2, varscan2
- AC099654.5 | n.80A>T | RNA (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- AC142381.4 | n.499+32221C>A | Intron (SNP) | VAF 80/397 reads (20%) | called by muse, mutect2, varscan2
- ADAM6 | n.1501G>C | RNA (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- ANAPC11 | c.110-528A>T | Intron (SNP) | VAF 178/546 reads (33%) | catalogued as rs374400220; called by muse, mutect2, varscan2
- ANK2 | c.*109C>G | 3'UTR (SNP) | VAF 53/378 reads (14%) | catalogued as COSV100002656; called by muse, mutect2, varscan2
- ASH1L | c.5828+4945C>G | Intron (SNP) | VAF 21/349 reads (6%) | called by muse, mutect2
- BAGE2 | n.48A>G | RNA (SNP) | VAF 103/491 reads (21%) | called by muse, mutect2, varscan2
- BMERB1 | c.502+787A>T | Intron (SNP) | VAF 40/271 reads (15%) | called by muse, mutect2, varscan2
- BPI | c.613-727T>A | Intron (SNP) | VAF 39/251 reads (16%) | called by muse, mutect2, varscan2
- CACTIN | c.*19+114T>C | Intron (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- CD47 | c.877+1950G>T | Intron (SNP) | VAF 26/200 reads (13%) | called by muse, mutect2, varscan2
- CES4A | c.260+246G>T | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- CHMP7 | c.299+1056G>C | Intron (SNP) | VAF 41/237 reads (17%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2945G>T | 3'UTR (SNP) | VAF 47/268 reads (18%) | called by muse, mutect2, varscan2
- CXCL12 | c.*275C>A | 3'UTR (SNP) | VAF 42/278 reads (15%) | catalogued as rs763415386, COSV59108030; called by muse, mutect2, varscan2
- DAAM2 | c.*2378G>T | 3'UTR (SNP) | VAF 58/395 reads (15%) | called by muse, mutect2, varscan2
- DAO | chr12:108880062 G>T | 5'Flank (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2
- DCHS2 | n.6310G>A | RNA (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.245-62G>C | Intron (SNP) | VAF 37/218 reads (17%) | called by muse, mutect2, varscan2
- EYS | c.1767-7723dup | Intron (INS) | VAF 14/61 reads (23%) | catalogued as rs1269796692; called by mutect2, varscan2
- FMN1 | c.2044-2710C>G | Intron (SNP) | VAF 29/218 reads (13%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1434T>C | 3'UTR (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- GNA12 | c.310-19736C>T | Intron (SNP) | VAF 66/216 reads (31%) | catalogued as rs761755558; called by muse, mutect2, varscan2
- HNRNPA3P1 | n.480C>G | RNA (SNP) | VAF 12/233 reads (5%) | called by muse, mutect2
- IL16 | c.1903-1424A>C | Intron (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- ISCA1P1 | n.103A>T | RNA (SNP) | VAF 13/243 reads (5%) | called by muse, mutect2
- LAMA4 | c.1078-1651C>G | Intron (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- LINC02740 | n.39T>A | RNA (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- LRP4 | c.4448+16G>A | Intron (SNP) | VAF 58/679 reads (9%) | called by muse, mutect2
- NAE1 | c.1238-50T>C | Intron (SNP) | VAF 30/88 reads (34%) | catalogued as rs1475372173; called by muse, mutect2, varscan2
- NDRG4 | c.-90G>T | 5'UTR (SNP) | VAF 43/90 reads (48%) | catalogued as rs938138636; called by muse, mutect2, varscan2
- NIPAL3 | c.637+567G>C | Intron (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31436A>G | Intron (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- NT5C3A | c.139-2785G>C | Intron (SNP) | VAF 27/211 reads (13%) | catalogued as rs1186455805; called by muse, mutect2, varscan2
- NTRK2 | c.1585+4425G>T | Intron (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.563G>T | RNA (SNP) | VAF 108/341 reads (32%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-739G>C | Intron (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- PDCD5 | c.-11G>C | 5'UTR (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- PRAME | c.21+906C>T | Intron (SNP) | VAF 69/128 reads (54%) | called by muse, mutect2, varscan2
- RASSF1 | c.369+598G>T | Intron (SNP) | VAF 145/206 reads (70%) | called by muse, mutect2, varscan2
- RASSF1 | c.369+337G>T | Intron (SNP) | VAF 50/72 reads (69%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85655151 A>T | 3'Flank (SNP) | VAF 130/1102 reads (12%) | called by mutect2, varscan2
- RNU6-389P | chr7:55685315 C>A | 5'Flank (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- RPL35 | c.-18T>C | 5'UTR (SNP) | VAF 87/244 reads (36%) | called by muse, mutect2, varscan2
- SMARCA4 | c.4171-1756A>G | Intron (SNP) | VAF 12/120 reads (10%) | catalogued as rs1276154532; called by muse, mutect2
- SNCAIP | c.-31T>G | 5'UTR (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3957T>A | Intron (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- TMCC2 | c.748-12606C>G | Intron (SNP) | VAF 14/454 reads (3%) | called by muse, mutect2
- TMEM225B | c.-17G>A | 5'UTR (SNP) | VAF 58/207 reads (28%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2099G>T | Intron (SNP) | VAF 43/320 reads (13%) | called by mutect2, varscan2
- TOX2 | c.*4C>T | 3'UTR (SNP) | VAF 27/407 reads (7%) | catalogued as rs747936062; called by muse, mutect2
- TRIM51EP | n.1146T>C | RNA (SNP) | VAF 12/29 reads (41%) | called by mutect2, varscan2
- TRPM4 | c.-38G>C | 5'UTR (SNP) | VAF 67/180 reads (37%) | catalogued as rs887318349; called by muse, mutect2, varscan2
- UBBP4 | n.896C>G | RNA (SNP) | VAF 186/632 reads (29%) | catalogued as rs749500953; called by muse, mutect2, varscan2
- WT1 | chr11:32439763 G>T | 5'Flank (SNP) | VAF 96/280 reads (34%) | catalogued as rs911932992; called by muse, mutect2, varscan2
- ZBTB44-DT | n.382T>C | RNA (SNP) | VAF 121/346 reads (35%) | called by muse, mutect2, varscan2
